Somatic mutation profile of tumor specimen MBCProject_3896_T4_WES (aliquot MBCProject_3896_T4_WES_1) from CMI case MBCProject_3896, project CMI-MBC: Count Me In (CMI): The Metastatic Breast Cancer (MBC) Project. Sex at birth: female; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; Age at diagnosis: 70.2 years (25,655 days).
Specimen MBCProject_3896_T4_WES: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lymph Node(s) Axilla; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c94b89a7-190b-4efb-9b00-bbf409a2464a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MBCProject_3896_SALIVA (Saliva), aliquot MBCProject_3896_SALIVA_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c740455b-e38f-4a49-836b-3cd67f6869e7

The open-access MAF lists 221 somatic variants for this specimen: 143 protein-altering or splice-affecting, 45 silent, 33 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 122, Silent 45, Intron 14, Nonsense Mutation 9, 5'UTR 6, Frame Shift Del 5, RNA 4, 3'UTR 4, Splice Site 3, 3'Flank 3, 5'Flank 2, Frame Shift Ins 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ESR1 | c.1609T>A p.Y537N | Missense Mutation (SNP) | VAF 160/471 reads (34%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV52784978, COSV52804811, COSV99237981; called by muse, mutect2, varscan2
- PIK3CA | c.3140A>G p.H1047R | Missense Mutation (SNP) | VAF 30/112 reads (27%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.085); catalogued as rs121913279, CM153086, COSV55873195, COSV55873401, COSV55888015; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ADAMTS9 | c.643G>C p.E215Q | Missense Mutation (SNP) | VAF 6/114 reads (5%) | SIFT tolerated (0.59); PolyPhen benign (0.001); catalogued as rs947383061; called by muse, mutect2
- ADAMTSL3 | c.994C>T p.Q332* | Nonsense Mutation (SNP) | VAF 25/118 reads (21%) | catalogued as COSV54446085, COSV99716519; called by muse, mutect2, varscan2
- ADH1A | c.887C>G p.P296R | Missense Mutation (SNP) | VAF 44/199 reads (22%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); catalogued as COSV52924648; called by muse, mutect2, varscan2
- ANKRD45 | c.452C>A p.A151D | Missense Mutation (SNP) | VAF 33/211 reads (16%) | SIFT tolerated (0.21); PolyPhen benign (0.001); catalogued as COSV100322686; called by muse, mutect2, varscan2
- APEX1 | c.729dup p.L244Tfs*8 | Frame Shift Ins (INS) | VAF 88/605 reads (15%) | catalogued as rs1451243040; called by mutect2, pindel, varscan2
- BMP4 | c.1207G>C p.E403Q | Missense Mutation (SNP) | VAF 33/202 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.66); catalogued as rs1237655395; called by muse, mutect2, varscan2
- CLEC9A | c.578C>G p.S193C | Missense Mutation (SNP) | VAF 53/196 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.819); catalogued as rs997271993; called by muse, mutect2, varscan2
- CNOT6 | c.602A>G p.Y201C | Missense Mutation (SNP) | VAF 26/83 reads (31%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as COSV56163640; called by muse, mutect2, varscan2
- CYTL1 | c.400C>T p.R134C | Missense Mutation (SNP) | VAF 77/395 reads (19%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.36); catalogued as rs137887145, COSV57037313; called by muse, mutect2, varscan2
- DCHS1 | c.521G>A p.R174H | Missense Mutation (SNP) | VAF 20/175 reads (11%) | SIFT tolerated (0.13); PolyPhen benign (0.001); catalogued as rs374282596, COSV55040917; called by muse, mutect2, varscan2
- EYS | c.5446G>A p.D1816N | Missense Mutation (SNP) | VAF 12/206 reads (6%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.001); catalogued as COSV58197499; called by muse, mutect2
- GLT6D1 | c.62G>A p.R21H | Missense Mutation (SNP) | VAF 13/69 reads (19%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as rs756561670, COSV65627142; called by muse, mutect2, varscan2
- HEY1 | c.440C>T p.S147F | Missense Mutation (SNP) | VAF 68/958 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.866); catalogued as COSV61232637; called by muse, mutect2
- HSPA13 | c.487C>T p.L163F | Missense Mutation (SNP) | VAF 90/283 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.104); catalogued as COSV53465501; called by muse, mutect2, varscan2
- IGHV1-18 | c.46G>A p.G16S | Missense Mutation (SNP) | VAF 33/272 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0.361); catalogued as rs561015233; called by muse, mutect2, varscan2
- LRRC36 | c.940G>A p.G314S | Missense Mutation (SNP) | VAF 39/154 reads (25%) | SIFT tolerated, low confidence (0.33); PolyPhen probably damaging (0.979); catalogued as rs544699196; called by muse, mutect2, varscan2
- LRRC74A | c.558G>C p.E186D | Missense Mutation (SNP) | VAF 15/127 reads (12%) | SIFT tolerated (0.55); PolyPhen benign (0.07); catalogued as rs760611288; called by muse, mutect2, varscan2
- MAP3K11 | c.2036C>A p.P679H | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as COSV58418356; called by mutect2, varscan2
- MCHR2 | c.623del p.F208Sfs*5 | Frame Shift Del (DEL) | VAF 18/84 reads (21%) | catalogued as rs759525627, COSV55999002; called by mutect2, varscan2
- MKI67 | c.1729G>T p.V577F | Missense Mutation (SNP) | VAF 68/189 reads (36%) | SIFT tolerated (0.88); PolyPhen benign (0); catalogued as COSV64077502; called by muse, mutect2, varscan2
- MUC5B | c.13419G>T p.Q4473H | Missense Mutation (SNP) | VAF 37/163 reads (23%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.003); catalogued as COSV101500297; called by muse, mutect2, varscan2
- MYO1D | c.1369G>A p.D457N | Missense Mutation (SNP) | VAF 41/204 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV59024000; called by muse, mutect2, varscan2
- N4BP2L2 | c.1640C>T p.S547L | Missense Mutation (SNP) | VAF 77/337 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV57227461; called by muse, mutect2, varscan2
- NES | c.2661G>C p.E887D | Missense Mutation (SNP) | VAF 17/98 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.026); catalogued as COSV104427526; called by muse, mutect2, varscan2
- OR1M1 | c.791C>T p.S264L | Missense Mutation (SNP) | VAF 17/53 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.687); catalogued as rs1332959232, COSV101447568, COSV101447600; called by muse, mutect2, varscan2
- PHACTR3 | c.83C>T p.S28L | Missense Mutation (SNP) | VAF 9/91 reads (10%) | SIFT tolerated (0.11); PolyPhen benign (0.005); catalogued as rs960726257; called by muse, mutect2, varscan2
- PLAGL2 | c.172C>T p.H58Y | Missense Mutation (SNP) | VAF 12/328 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.245); catalogued as COSV55787472; called by muse, mutect2
- POF1B | c.370C>G p.P124A | Missense Mutation (SNP) | VAF 41/132 reads (31%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.994); catalogued as rs757732492; called by muse, mutect2, varscan2
- PPIP5K2 | c.3649C>T p.P1217S (on ENST00000358359 / NM_001276277.3; = p.P1196S on NM_015216.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 66/246 reads (27%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0); catalogued as rs782146288; called by muse, varscan2
- PREX2 | c.64C>T p.R22C | Missense Mutation (SNP) | VAF 177/915 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV55749568; called by muse, mutect2, varscan2
- PTAFR | c.151G>A p.E51K | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as COSV59536724; called by muse, mutect2, varscan2
- RAD50 | c.1982G>C p.G661A | Missense Mutation (SNP) | VAF 32/230 reads (14%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.93); catalogued as rs758063640; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RAD51C | c.1040G>C p.R347T | Missense Mutation (SNP) | VAF 32/235 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV100506977; called by muse, mutect2, varscan2
- RADIL | c.2623C>A p.P875T | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as rs758342576; called by muse, mutect2
- RASGRP4 | c.1960G>C p.D654H | Missense Mutation (SNP) | VAF 42/344 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.347); catalogued as rs1260039971; called by muse, mutect2, varscan2
- RPTOR | c.2045C>T p.A682V | Missense Mutation (SNP) | VAF 11/83 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.948); catalogued as rs770209703; called by muse, mutect2, varscan2
- SLCO4A1 | c.887G>A p.R296Q | Missense Mutation (SNP) | VAF 26/388 reads (7%) | SIFT tolerated (0.44); PolyPhen benign (0.022); catalogued as rs560952826; called by muse, mutect2
- SLFN12 | c.556G>C p.D186H | Missense Mutation (SNP) | VAF 20/75 reads (27%) | SIFT tolerated (0.09); PolyPhen benign (0.154); catalogued as COSV59227284; called by muse, mutect2, varscan2
- SLITRK5 | c.1722G>T p.M574I | Missense Mutation (SNP) | VAF 13/287 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.048); catalogued as COSV61523830; called by muse, mutect2
- SRPK2 | c.923C>T p.S308L | Missense Mutation (SNP) | VAF 57/337 reads (17%) | SIFT tolerated (0.22); PolyPhen benign (0.011); catalogued as rs1340874246, COSV100624330, COSV61963906; called by muse, mutect2, varscan2
- SUPT6H | c.3540G>C p.Q1180H | Missense Mutation (SNP) | VAF 22/113 reads (19%) | SIFT deleterious (0.05); PolyPhen benign (0.142); catalogued as COSV100112207; called by muse, mutect2, varscan2
- TBC1D10A | c.903G>C p.K301N | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.904); catalogued as rs749396893; called by muse, mutect2, varscan2
- TBC1D2 | c.1309C>G p.P437A | Missense Mutation (SNP) | VAF 51/175 reads (29%) | SIFT tolerated (0.46); PolyPhen benign (0.027); catalogued as rs375721269; called by muse, mutect2, varscan2
- TMEM161B | c.547A>G p.M183V | Missense Mutation (SNP) | VAF 72/299 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.089); catalogued as rs369774401; called by muse, mutect2, varscan2
- TNFRSF10A | c.1177G>A p.E393K | Missense Mutation (SNP) | VAF 14/321 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV55325479; called by muse, mutect2
- TP53BP1 | c.76C>T p.Q26* | Nonsense Mutation (SNP) | VAF 52/100 reads (52%) | catalogued as COSV99781802; called by muse, mutect2, varscan2
- TRAF7 | c.1640G>T p.R547L | Missense Mutation (SNP) | VAF 11/55 reads (20%) | SIFT tolerated (0.4); PolyPhen benign (0.018); catalogued as rs781270559, COSV58214204; called by muse, mutect2, varscan2
- TRIM10 | c.250C>T p.R84C | Missense Mutation (SNP) | VAF 61/376 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.791); catalogued as rs769419657, COSV100938926, COSV64989187; called by muse, mutect2, varscan2
- TTLL11 | c.919C>T p.R307C | Missense Mutation (SNP) | VAF 18/79 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as rs138558032; called by muse, mutect2, varscan2
- TTN | c.76948G>A p.E25650K (on ENST00000591111; = p.E18226K on NM_003319.4) | Missense Mutation (SNP) | VAF 86/232 reads (37%) | PolyPhen benign (0.254); catalogued as COSV60187286; called by muse, mutect2, varscan2
- UNKL | c.1682C>T p.S561L | Missense Mutation (SNP) | VAF 48/285 reads (17%) | SIFT tolerated (0.77); PolyPhen benign (0.06); catalogued as rs574913319, COSV50190477, COSV99201402; called by muse, mutect2, varscan2
- USH2A | c.11488C>T p.L3830F | Missense Mutation (SNP) | VAF 24/513 reads (5%) | SIFT tolerated (0.24); PolyPhen benign (0.039); catalogued as COSV100232460; called by muse, mutect2
- ZNF451 | c.1195T>A p.L399I | Missense Mutation (SNP) | VAF 47/276 reads (17%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.784); catalogued as COSV62597107, COSV62598161; called by muse, mutect2, varscan2
- ABCF1 | c.1393G>A p.A465T (on ENST00000326195 / NM_001025091.2; = p.A427T on NM_001090.3) | Missense Mutation (SNP) | VAF 36/169 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ADAM11 | c.373C>T p.H125Y | Missense Mutation (SNP) | VAF 15/78 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.102); called by muse, mutect2, varscan2
- ADAMTS5 | c.2289C>G p.F763L | Missense Mutation (SNP) | VAF 29/120 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.192); called by muse, mutect2, varscan2
- ADGRE5 | c.1188_1200del p.A397Sfs*7 (on ENST00000242786 / NM_078481.4; = p.A304Sfs*7 on NM_001784.5) | Frame Shift Del (DEL) | VAF 14/57 reads (25%) | called by mutect2, pindel, varscan2
- ARHGEF10 | c.2349_2350del p.V784Sfs*3 (on ENST00000398564; = p.V759Sfs*3 on NM_014629.4) | Frame Shift Del (DEL) | VAF 63/210 reads (30%) | called by mutect2, pindel, varscan2
- ARL6 | c.371C>A p.P124Q | Missense Mutation (SNP) | VAF 39/170 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ARMC2 | c.2262G>C p.L754F | Missense Mutation (SNP) | VAF 37/114 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ATN1 | c.2333C>T p.A778V | Missense Mutation (SNP) | VAF 27/159 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.488); called by muse, mutect2, varscan2
- BAALC | c.25G>T p.D9Y | Missense Mutation (SNP) | VAF 78/827 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.77); called by muse, mutect2
- BATF | c.229G>T p.E77* | Nonsense Mutation (SNP) | VAF 51/229 reads (22%) | called by muse, mutect2, varscan2
- BUB1B | c.352G>A p.D118N | Missense Mutation (SNP) | VAF 46/97 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- C16orf71 | c.887A>T p.H296L | Missense Mutation (SNP) | VAF 20/78 reads (26%) | SIFT tolerated (0.42); PolyPhen benign (0); called by muse, mutect2, varscan2
- C16orf86 | c.932dup p.L312Afs*21 | Frame Shift Ins (INS) | VAF 49/246 reads (20%) | called by mutect2, pindel, varscan2
- CAMKMT | c.104C>A p.P35H | Missense Mutation (SNP) | VAF 23/75 reads (31%) | SIFT tolerated (0.06); PolyPhen benign (0.241); called by muse, mutect2, varscan2
- CEP83 | c.244G>A p.E82K | Missense Mutation (SNP) | VAF 46/267 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.976); called by mutect2, varscan2
- CMYA5 | c.8154G>C p.E2718D | Missense Mutation (SNP) | VAF 20/195 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- CRYBG2 | c.3949C>T p.Q1317* | Nonsense Mutation (SNP) | VAF 62/204 reads (30%) | called by muse, mutect2, varscan2
- DAP | c.308G>T p.*103Lext*20 | Nonstop Mutation (SNP) | VAF 10/36 reads (28%) | called by muse, mutect2, varscan2
- DIO3 | c.295C>G p.P99A | Missense Mutation (SNP) | VAF 13/107 reads (12%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DRD1 | c.541G>A p.E181K | Missense Mutation (SNP) | VAF 19/101 reads (19%) | SIFT tolerated (0.85); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- EGFLAM | c.177G>C p.R59S | Missense Mutation (SNP) | VAF 30/96 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.403); called by muse, mutect2, varscan2
- EIF2AK2 | c.1540C>A p.L514I | Missense Mutation (SNP) | VAF 66/97 reads (68%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- EPM2A | c.525G>A p.M175I | Missense Mutation (SNP) | VAF 23/121 reads (19%) | SIFT tolerated, low confidence (0.09); called by muse, mutect2, varscan2
- FAM111B | c.1654G>C p.E552Q | Missense Mutation (SNP) | VAF 27/116 reads (23%) | SIFT tolerated (0.25); PolyPhen benign (0.397); called by muse, mutect2, varscan2
- GCNT4 | c.190A>T p.K64* | Nonsense Mutation (SNP) | VAF 36/130 reads (28%) | called by muse, mutect2, varscan2
- GDPD2 | c.117C>G p.I39M | Missense Mutation (SNP) | VAF 30/122 reads (25%) | SIFT tolerated (0.13); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- GRAMD1C | c.314C>G p.S105* | Nonsense Mutation (SNP) | VAF 16/64 reads (25%) | called by muse, mutect2, varscan2
- GSDME | c.857A>C p.K286T | Missense Mutation (SNP) | VAF 32/221 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.054); called by muse, mutect2, varscan2
- GSTA4 | c.403G>T p.V135L | Missense Mutation (SNP) | VAF 32/168 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.75); called by muse, mutect2, varscan2
- HDAC3 | c.655C>G p.L219V | Missense Mutation (SNP) | VAF 45/281 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- HK3 | c.2470A>T p.M824L | Missense Mutation (SNP) | VAF 16/65 reads (25%) | SIFT tolerated (0.57); PolyPhen benign (0); called by muse, mutect2, varscan2
- HLA-DQA2 | c.621G>C p.E207D | Missense Mutation (SNP) | VAF 30/500 reads (6%) | SIFT tolerated (0.08); PolyPhen benign (0.012); called by muse, mutect2
- HMCN1 | c.5011C>T p.P1671S | Missense Mutation (SNP) | VAF 20/364 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- HOMER1 | c.550G>C p.E184Q | Missense Mutation (SNP) | VAF 26/177 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- IGHV1OR21-1 | c.332C>A p.A111D | Missense Mutation (SNP) | VAF 18/302 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- IL19 | c.361T>C p.C121R | Missense Mutation (SNP) | VAF 46/333 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- IQCB1 | c.592G>C p.D198H | Missense Mutation (SNP) | VAF 29/123 reads (24%) | SIFT tolerated (0.56); PolyPhen benign (0.376); called by muse, mutect2, varscan2
- IWS1 | c.982G>C p.E328Q | Missense Mutation (SNP) | VAF 73/250 reads (29%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- JAG2 | c.476-1G>C p.X159_splice | Splice Site (SNP) | VAF 8/52 reads (15%) | called by muse, mutect2
- JAKMIP2 | c.1315G>A p.E439K | Missense Mutation (SNP) | VAF 34/268 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.031); called by muse, varscan2
- KLK4 | c.227C>A p.S76Y | Missense Mutation (SNP) | VAF 26/434 reads (6%) | SIFT tolerated (0.6); PolyPhen probably damaging (0.99); called by muse, mutect2
- KMT2C | c.7238C>T p.A2413V | Missense Mutation (SNP) | VAF 58/317 reads (18%) | SIFT tolerated (0.23); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- KRT7 | c.46G>C p.A16P | Missense Mutation (SNP) | VAF 34/133 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- LRP1 | c.2665C>G p.L889V | Missense Mutation (SNP) | VAF 27/77 reads (35%) | SIFT tolerated (0.32); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- MUC16 | c.22127G>T p.G7376V | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.136); called by muse, mutect2, varscan2
- MYH6 | c.4156G>T p.E1386* | Nonsense Mutation (SNP) | VAF 27/216 reads (13%) | called by muse, mutect2, varscan2
- MYO18B | c.542C>G p.S181C | Missense Mutation (SNP) | VAF 19/47 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.303); called by muse, mutect2, varscan2
- NARS2 | c.305C>A p.P102Q | Missense Mutation (SNP) | VAF 54/239 reads (23%) | SIFT tolerated (0.15); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- NFXL1 | c.1268A>C p.E423A | Missense Mutation (SNP) | VAF 62/227 reads (27%) | SIFT tolerated (0.14); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- NUP107 | c.29C>T p.S10L | Missense Mutation (SNP) | VAF 65/172 reads (38%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0); called by muse, mutect2, varscan2
- NWD1 | c.2347G>A p.E783K | Missense Mutation (SNP) | VAF 30/110 reads (27%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.787); called by muse, mutect2, varscan2
- OR5M3 | c.380C>A p.P127H | Missense Mutation (SNP) | VAF 61/204 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); called by muse, mutect2, varscan2
- PALM | c.675C>A p.H225Q | Missense Mutation (SNP) | VAF 28/104 reads (27%) | SIFT tolerated (0.25); PolyPhen benign (0.067); called by muse, mutect2, varscan2
- PAX1 | c.765_786del p.Y256Rfs*64 | Frame Shift Del (DEL) | VAF 6/44 reads (14%) | called by mutect2, pindel
- PCM1 | c.2193-1G>C p.X731_splice | Splice Site (SNP) | VAF 24/191 reads (13%) | called by muse, mutect2, varscan2
- PIEZO2 | c.8C>A p.S3* | Nonsense Mutation (SNP) | VAF 42/131 reads (32%) | called by muse, mutect2, varscan2
- PLEKHG5 | c.2281G>T p.G761C (on ENST00000400915 / NM_001042663.3; = p.G724C on NM_020631.6) | Missense Mutation (SNP) | VAF 23/61 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.319); called by mutect2, varscan2
- PRKDC | c.941C>T p.S314L | Missense Mutation (SNP) | VAF 45/340 reads (13%) | SIFT tolerated (0.53); PolyPhen benign (0.049); called by muse, mutect2, varscan2
- PSKH1 | c.220C>T p.P74S | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT tolerated (0.74); PolyPhen benign (0); called by muse, mutect2, varscan2
- PSKH1 | c.685C>G p.P229A | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.823); called by muse, mutect2, varscan2
- QSOX1 | c.1657A>T p.R553W | Missense Mutation (SNP) | VAF 51/92 reads (55%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.706); called by muse, mutect2, varscan2
- RAD50 | c.1818G>C p.Q606H | Missense Mutation (SNP) | VAF 55/260 reads (21%) | SIFT tolerated (0.08); PolyPhen benign (0.283); called by muse, mutect2, varscan2
- RAD50 | c.2205G>A p.M735I | Missense Mutation (SNP) | VAF 76/411 reads (18%) | SIFT tolerated (0.41); PolyPhen benign (0); called by muse, mutect2, varscan2
- RBM19 | c.995A>C p.K332T | Missense Mutation (SNP) | VAF 22/95 reads (23%) | SIFT tolerated (0.13); PolyPhen benign (0.076); called by muse, mutect2, varscan2
- RTP5 | c.1133A>C p.K378T | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT deleterious (0.05); PolyPhen benign (0.088); called by muse, mutect2, varscan2
- RXFP1 | c.1046G>T p.S349I | Missense Mutation (SNP) | VAF 12/68 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.52); called by muse, mutect2, varscan2
- SCN3A | c.3184A>C p.N1062H | Missense Mutation (SNP) | VAF 37/161 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SCUBE1 | c.485-1G>C p.X162_splice | Splice Site (SNP) | VAF 5/40 reads (13%) | called by muse, mutect2, varscan2
- SIRT4 | c.413A>T p.Y138F | Missense Mutation (SNP) | VAF 81/269 reads (30%) | SIFT tolerated (0.08); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- SLC22A17 | n.1281A>T | Splice Region (SNP) | VAF 22/116 reads (19%) | called by muse, mutect2, varscan2
- SMARCA2 | c.4570G>A p.D1524N | Missense Mutation (SNP) | VAF 36/110 reads (33%) | SIFT tolerated (0.13); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- SNX13 | c.1822T>A p.F608I | Missense Mutation (SNP) | VAF 15/103 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.491); called by muse, mutect2, varscan2
- SPINK5 | c.1961_1986del p.R654Qfs*7 | Frame Shift Del (DEL) | VAF 47/396 reads (12%) | called by mutect2, pindel
- STAB2 | c.5198C>A p.P1733H | Missense Mutation (SNP) | VAF 53/188 reads (28%) | SIFT tolerated (0.08); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- TBKBP1 | c.700G>A p.E234K | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.985); called by muse, mutect2
- TENM2 | c.2845G>C p.V949L (on ENST00000518659 / NM_001122679.2; = p.V717L on NM_001080428.3) | Missense Mutation (SNP) | VAF 61/179 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- TNRC6A | c.3427G>A p.E1143K | Missense Mutation (SNP) | VAF 28/258 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.813); called by muse, mutect2
- TOGARAM1 | c.5060C>A p.A1687E | Missense Mutation (SNP) | VAF 58/371 reads (16%) | SIFT tolerated (0.17); PolyPhen benign (0.284); called by muse, mutect2, varscan2
- TRAV21 | c.212C>T p.S71L | Missense Mutation (SNP) | VAF 16/359 reads (4%) | SIFT deleterious (0.05); PolyPhen benign (0.299); called by muse, mutect2
- VDAC1 | c.529G>A p.E177K | Missense Mutation (SNP) | VAF 27/157 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- WRNIP1 | c.325G>A p.E109K | Missense Mutation (SNP) | VAF 28/92 reads (30%) | SIFT tolerated, low confidence (0.36); PolyPhen possibly damaging (0.651); called by muse, mutect2, varscan2
- YIF1B | c.767G>A p.C256Y (on ENST00000339413 / NM_001039673.3; = p.C241Y on NM_001039671.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 36/778 reads (5%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.936); called by muse, mutect2
- ZFYVE26 | c.2997G>C p.L999F | Missense Mutation (SNP) | VAF 59/321 reads (18%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZNF229 | c.1410C>G p.F470L | Missense Mutation (SNP) | VAF 29/636 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.031); called by muse, mutect2
- ZNF320 | c.1051C>T p.H351Y | Missense Mutation (SNP) | VAF 24/179 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.499); called by muse, mutect2, varscan2
- ZNF546 | c.2416C>T p.Q806* | Nonsense Mutation (SNP) | VAF 18/197 reads (9%) | called by muse, mutect2
- ZNF551 | c.409A>T p.S137C | Missense Mutation (SNP) | VAF 28/402 reads (7%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- ZNF574 | c.776C>T p.A259V | Missense Mutation (SNP) | VAF 18/76 reads (24%) | SIFT tolerated (0.62); PolyPhen benign (0); called by muse, mutect2, varscan2
- ADCK5 | c.507G>A p.V169= | Silent (SNP) | VAF 20/312 reads (6%) | called by muse, mutect2
- AEBP2 | c.312C>T p.F104= | Silent (SNP) | VAF 9/77 reads (12%) | catalogued as rs1372348426; called by muse, mutect2, varscan2
- ANKDD1B | c.1179C>T p.Y393= | Silent (SNP) | VAF 18/242 reads (7%) | catalogued as rs1249267737, COSV101552586; called by muse, mutect2
- APBA1 | c.1812C>T p.I604= | Silent (SNP) | VAF 18/80 reads (23%) | catalogued as rs371740590; called by muse, mutect2, varscan2
- ARFIP2 | c.999G>A p.E333= | Silent (SNP) | VAF 30/108 reads (28%) | called by muse, mutect2, varscan2
- ARFRP1 | c.492G>T p.L164= | Silent (SNP) | VAF 28/198 reads (14%) | called by muse, mutect2, varscan2
- ATAD2 | c.117C>G p.L39= | Silent (SNP) | VAF 41/712 reads (6%) | catalogued as COSV54877507; called by muse, mutect2
- CAMK1D | c.777G>C p.L259= | Silent (SNP) | VAF 20/89 reads (22%) | called by muse, mutect2, varscan2
- CBL | c.729C>A p.I243= | Silent (SNP) | VAF 63/279 reads (23%) | called by muse, mutect2, varscan2
- CBX8 | c.600C>T p.G200= | Silent (SNP) | VAF 42/214 reads (20%) | catalogued as rs757296700; called by muse, mutect2, varscan2
- DMRTA1 | c.927C>G p.V309= | Silent (SNP) | VAF 67/213 reads (31%) | called by muse, mutect2, varscan2
- DNAH8 | c.11109C>T p.I3703= | Silent (SNP) | VAF 35/178 reads (20%) | catalogued as COSV100547447; called by muse, mutect2, varscan2
- DOCK5 | c.4461C>T p.T1487= | Silent (SNP) | VAF 22/157 reads (14%) | called by muse, mutect2, varscan2
- DPH2 | c.1419G>A p.V473= | Silent (SNP) | VAF 41/144 reads (28%) | called by muse, mutect2, varscan2
- FAM171A1 | c.1599C>T p.D533= | Silent (SNP) | VAF 26/86 reads (30%) | called by muse, mutect2, varscan2
- GRIA1 | c.147C>T p.L49= | Silent (SNP) | VAF 41/247 reads (17%) | called by muse, mutect2, varscan2
- GRIK3 | c.1254G>A p.E418= | Silent (SNP) | VAF 23/99 reads (23%) | called by muse, mutect2, varscan2
- GRM5 | c.855T>A p.G285= | Silent (SNP) | VAF 30/467 reads (6%) | catalogued as rs768609538; called by muse, mutect2
- HBA2 | c.345C>T p.P115= | Silent (SNP) | VAF 78/470 reads (17%) | catalogued as CD066366, COSV52406697; called by muse, mutect2, varscan2
- HSPA8 | c.591C>T p.I197= | Silent (SNP) | VAF 21/90 reads (23%) | catalogued as COSV57083664; called by muse, mutect2, varscan2
- KCNH4 | c.1458G>T p.S486= | Silent (SNP) | VAF 26/133 reads (20%) | called by muse, mutect2, varscan2
- KRT37 | c.411C>T p.L137= | Silent (SNP) | VAF 11/305 reads (4%) | catalogued as rs762388047, COSV56656819; called by muse, mutect2
- MARCHF6 | c.2241G>C p.L747= | Silent (SNP) | VAF 86/369 reads (23%) | catalogued as COSV99930080; called by muse, mutect2, varscan2
- MED13 | c.3102C>T p.V1034= | Silent (SNP) | VAF 24/137 reads (18%) | called by muse, mutect2, varscan2
- MRPL14 | c.18G>T p.G6= | Silent (SNP) | VAF 35/207 reads (17%) | called by muse, mutect2, varscan2
- MYLK | c.2217C>A p.L739= | Silent (SNP) | VAF 40/153 reads (26%) | called by muse, mutect2, varscan2
- P2RX2 | c.687C>T p.H229= (on ENST00000343948 / NM_170683.4; = p.H157= on NM_012226.5) | Silent (SNP) | VAF 28/187 reads (15%) | catalogued as rs754679844; called by muse, mutect2, varscan2
- PAX1 | c.96G>A p.A32= | Silent (SNP) | VAF 6/20 reads (30%) | catalogued as rs1302813262; called by mutect2, varscan2
- PLPBP | c.429C>A p.V143= | Silent (SNP) | VAF 15/194 reads (8%) | called by muse, mutect2
- PRX | c.4350G>A p.P1450= | Silent (SNP) | VAF 12/150 reads (8%) | catalogued as rs768051108; called by muse, mutect2
- PSMB6 | c.384G>A p.L128= | Silent (SNP) | VAF 37/147 reads (25%) | called by muse, mutect2, varscan2
- RAB19 | c.36G>A p.E12= | Silent (SNP) | VAF 29/118 reads (25%) | called by muse, mutect2, varscan2
- RHBDF1 | c.1935C>G p.L645= | Silent (SNP) | VAF 6/46 reads (13%) | called by muse, mutect2
- RRS1 | c.654G>A p.L218= | Silent (SNP) | VAF 269/377 reads (71%) | called by muse, mutect2, varscan2
- SKIDA1 | c.138C>T p.H46= | Silent (SNP) | VAF 25/247 reads (10%) | called by muse, mutect2, varscan2
- SLC6A16 | c.306C>A p.A102= | Silent (SNP) | VAF 32/143 reads (22%) | called by muse, mutect2, varscan2
- TOPAZ1 | c.2769A>G p.E923= | Silent (SNP) | VAF 10/60 reads (17%) | called by muse, varscan2
- TRIM23 | c.999A>G p.S333= | Silent (SNP) | VAF 72/336 reads (21%) | called by muse, mutect2, varscan2
- TRIM65 | c.69G>A p.V23= | Silent (SNP) | VAF 34/239 reads (14%) | called by muse, mutect2, varscan2
- TRMT61B | c.216G>C p.L72= | Silent (SNP) | VAF 20/55 reads (36%) | called by muse, mutect2, varscan2
- URB1 | c.5994G>A p.L1998= | Silent (SNP) | VAF 18/79 reads (23%) | called by muse, mutect2, varscan2
- UTP20 | c.2604G>C p.R868= | Silent (SNP) | VAF 51/193 reads (26%) | called by muse, mutect2, varscan2
- ZFHX4 | c.624T>C p.D208= | Silent (SNP) | VAF 103/571 reads (18%) | called by muse, mutect2, varscan2
- ZNF254 | c.1527G>A p.K509= | Silent (SNP) | VAF 10/180 reads (6%) | called by muse, mutect2
- ZNF646 | c.2949G>A p.G983= | Silent (SNP) | VAF 10/56 reads (18%) | catalogued as rs373982672; called by muse, mutect2, varscan2
- AC018638.4 | n.358C>T | RNA (SNP) | VAF 200/480 reads (42%) | called by muse, mutect2, varscan2
- AGBL3 | c.-15C>G | 5'UTR (SNP) | VAF 32/251 reads (13%) | catalogued as COSV99310432; called by muse, mutect2, varscan2
- ALDH6A1 | c.*2944T>G | 3'UTR (SNP) | VAF 9/38 reads (24%) | called by muse, mutect2, varscan2
- AP003062.1 | n.937T>C | RNA (SNP) | VAF 56/254 reads (22%) | catalogued as rs1396586529; called by muse, mutect2, varscan2
- C19orf84 | c.35+23G>A | Intron (SNP) | VAF 13/140 reads (9%) | called by muse, mutect2, varscan2
- CCNH | c.933+21G>T | Intron (SNP) | VAF 24/174 reads (14%) | catalogued as COSV99170282; called by muse, varscan2
- CEP295 | chr11:93735132 C>G | 3'Flank (SNP) | VAF 9/42 reads (21%) | called by muse, mutect2, varscan2
- CICP23 | chr11:130897 T>A | 3'Flank (SNP) | VAF 6/6 reads (100%) | called by mutect2, varscan2
- CIRBP | chr19:1268280 G>T | 5'Flank (SNP) | VAF 6/22 reads (27%) | called by muse, mutect2
- DHX30 | c.125-2211C>A | Intron (SNP) | VAF 29/58 reads (50%) | called by muse, mutect2, varscan2
- DISP2 | c.-32C>T | 5'UTR (SNP) | VAF 17/35 reads (49%) | called by muse, mutect2, varscan2
- FAM181A | c.-35C>A | 5'UTR (SNP) | VAF 81/120 reads (68%) | called by muse, mutect2, varscan2
- GABPB1 | c.-1+568C>G | Intron (SNP) | VAF 47/231 reads (20%) | called by muse, mutect2, varscan2
- GLYR1 | c.155+1434_155+1441del | Intron (DEL) | VAF 31/140 reads (22%) | called by mutect2, pindel, varscan2
- GUSBP10 | n.169G>A | RNA (SNP) | VAF 8/55 reads (15%) | catalogued as rs1248381944; called by muse, mutect2, varscan2
- IMMP2L | c.239+95260C>G | Intron (SNP) | VAF 15/178 reads (8%) | catalogued as rs1227465111; called by muse, mutect2
- KCNAB1 | c.276-129664G>A | Intron (SNP) | VAF 74/330 reads (22%) | called by muse, mutect2, varscan2
- LTBP3 | c.*19C>T | 3'UTR (SNP) | VAF 15/54 reads (28%) | called by muse, mutect2, varscan2
- MASP1 | c.1091-47G>T | Intron (SNP) | VAF 28/128 reads (22%) | called by muse, mutect2, varscan2
- MKI67 | c.-18C>G | 5'UTR (SNP) | VAF 75/285 reads (26%) | called by muse, mutect2, varscan2
- MMADHC | c.9+16C>T | Intron (SNP) | VAF 97/297 reads (33%) | catalogued as rs774042094; called by muse, mutect2, varscan2
- MPV17 | c.71-33G>C | Intron (SNP) | VAF 33/102 reads (32%) | catalogued as rs1445492059; called by muse, mutect2, varscan2
- PAQR5 | c.513-48G>A | Intron (SNP) | VAF 25/86 reads (29%) | catalogued as rs1264253481; called by muse, mutect2, varscan2
- PHF2 | c.*1606G>C | 3'UTR (SNP) | VAF 36/119 reads (30%) | called by muse, mutect2, varscan2
- PRKAG2 | c.1233+21C>A | Intron (SNP) | VAF 10/189 reads (5%) | called by muse, mutect2
- PRND | chr20:4732519 G>T | 3'Flank (SNP) | VAF 38/319 reads (12%) | called by muse, mutect2, varscan2
- RAD51C | c.-1G>T | 5'UTR (SNP) | VAF 60/411 reads (15%) | catalogued as rs750045091; called by muse, mutect2, varscan2
- SPATA31C1 | n.3472G>C | RNA (SNP) | VAF 45/156 reads (29%) | called by muse, mutect2, varscan2
- TBC1D12 | c.-3C>T | 5'UTR (SNP) | VAF 45/107 reads (42%) | catalogued as rs776687705, COSV56552223; called by muse, mutect2, varscan2
- TRIM25 | c.*884G>T | 3'UTR (SNP) | VAF 15/441 reads (3%) | called by muse, mutect2
- YPEL2 | c.117+127C>T | Intron (SNP) | VAF 20/120 reads (17%) | catalogued as rs754283120; called by muse, mutect2, varscan2
- ZBTB37 | chr1:173864160 del T | 5'Flank (DEL) | VAF 11/107 reads (10%) | called by mutect2, pindel, varscan2
- ZNF662 | c.-94+175A>C | Intron (SNP) | VAF 65/118 reads (55%) | called by muse, mutect2, varscan2
